Gene-level copy-number profile of tumor specimen TCGA-N9-A4Q4-01A from TCGA case TCGA-N9-A4Q4, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC; Age at diagnosis: 61.8 years (22,575 days).
Specimen TCGA-N9-A4Q4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.1b92293c-ef49-41eb-9d6e-5557fd428fbe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4Q4-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6fbfafb-7997-4258-a42f-650180278afa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 114; copy number 2: 17,352; copy number 3: 15,593; copy number 4: 21,855; copy number 5: 2,212; copy number 6: 1,752; copy number 7: 652; copy number 8: 50; copy number 9: 52; copy number 10: 92; copy number 11: 14; copy number 13: 13; copy number 14: 10; copy number 15: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4Q4-01A-11D-A28Q-01): tumor purity 0.94, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:9,292,588–9,398,579, 4 genes: AC026191.1, PGAM1P4, THUMPD3-AS1, THUMPD3.
- chr3:50,191,610–50,367,923, 24 genes: GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115.
- chr3:50,365,334–50,368,197, 1 gene: Z84492.1.
- chr4:150,422,645–150,423,642, 1 gene: AC092612.1.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 193 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:29,319,554–29,352,214, 1 gene, copy number 9: AC074096.1.
- chr3:168,858,659–169,038,416, 5 genes, copy number 9: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr4:1,550,284–1,982,207, 12 genes, copy number 10: AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22.
- chr4:1,986,384–1,986,477, 1 gene, copy number 10: MIR943.
- chr8:54,191,582–54,479,963, 9 genes, copy number 14: AC060764.1, AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 14: SEC11B.
- chr8:143,579,697–144,086,216, 38 genes, copy number 9 (within-gene range 5–9): EEF1D, TIGD5, PYCR3, GFUS, AC067930.2, ZNF623, ZNF707, LINC02878, CCDC166, AC105219.2, MAPK15, AC105219.1, FAM83H, MIR4664, IQANK1, AC105219.3, SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1, AC109322.2, PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1.
- chr11:95,571,040–95,963,624, 8 genes, copy number 9: AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1.
- chr19:27,638,483–30,228,715, 63 genes, copy number 10–13 (broad region; genes not listed).
- chr20:31,274,170–32,439,319, 55 genes, copy number 10–15 (within-gene range 3–15): DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.

Autosomal genes at a single copy (total copy number 1): 114. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
